Somatic mutation profile of tumor specimen C3L-00907-03 (aliquot CPT0064390009) from CPTAC case C3L-00907, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.8 years (20,369 days).
Specimen C3L-00907-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b87da9d-ba8d-43da-b1e9-5ea07d36347b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00907-31 (Blood Derived Normal), aliquot CPT0065420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea724b4b-5ba0-4b2a-b414-34bbb946df80

The open-access MAF lists 59 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 7, Intron 4, Splice Region 4, RNA 2, 3'UTR 2, In Frame Del 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM5C | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518697, BM1323210, COSV100949576, COSV64762787; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 131/472 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs5030807, CM941368, COSV56543066, COSV56543312, COSV56543561; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs752916520, COSV68067373, COSV68069242; called by muse, mutect2, varscan2
- ADCY4 | c.931-4C>T | Splice Region (SNP) | VAF 37/194 reads (19%) | catalogued as rs1258704765; called by muse, mutect2, varscan2
- FOXF1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs1030195503; called by muse, mutect2, varscan2
- GRHPR | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 94/493 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs952908719; called by muse, mutect2, varscan2
- MEFV | c.1760-5C>T | Splice Region (SNP) | VAF 84/474 reads (18%) | catalogued as rs1319612887; called by muse, mutect2
- MTG1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs559297659, COSV100448997; called by muse, mutect2, varscan2
- OR1C1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101376249; called by muse, mutect2, varscan2
- PAK6 | c.-116C>T | Splice Region (SNP) | VAF 41/185 reads (22%) | catalogued as rs1460458488; called by muse, mutect2, varscan2
- PCDHA7 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 133/826 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs781943368; called by muse, mutect2, varscan2
- PPM1A | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs865808535; called by muse, mutect2, varscan2
- PRM2 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99617703; called by muse, mutect2, varscan2
- REPIN1 | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.649); catalogued as rs770215207; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs780882235; called by muse, mutect2, varscan2
- ZNF513 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV52008679; called by muse, mutect2, varscan2
- ABCC1 | c.1702T>A p.Y568N | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AMY2A | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- BHMG1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- BLZF1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.825A>C p.E275D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAF2 | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 8/211 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLS | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HEATR3 | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HELLS | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- HMCN2 | c.4541C>A p.P1514Q | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- IL10 | c.300C>G p.N100K | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MAB21L4 | c.905T>A p.L302Q (on ENST00000388934 / NM_001085437.3; = p.L134Q on NM_024861.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPK6 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MIOX | c.341-7_341-6insA | Splice Region (INS) | VAF 18/102 reads (18%) | called by mutect2, pindel, varscan2
- NRBP1 | c.1572_1574del p.T525del | In Frame Del (DEL) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- NUP214 | c.5596T>C p.S1866P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PBRM1 | c.44_50del p.V15Gfs*28 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by pindel, varscan2
- PCYOX1 | c.773G>C p.C258S | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PGAP6 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POGK | c.1643T>A p.L548Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PTPRJ | c.3875A>G p.N1292S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCGN | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- SMG1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); called by muse, mutect2
- SRGAP3 | c.801+1del p.X267_splice | Splice Site (DEL) | VAF 55/280 reads (20%) | called by mutect2, pindel, varscan2
- TMEM108 | c.1328C>G p.T443R | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- ZBTB49 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZNF281 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 77/444 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BORA | c.118T>C p.L40= | Silent (SNP) | VAF 51/230 reads (22%) | called by muse, mutect2, varscan2
- CRIM1 | c.1773G>A p.K591= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs756989756; called by muse, mutect2, varscan2
- ECHDC3 | c.474T>G p.V158= | Silent (SNP) | VAF 68/346 reads (20%) | called by muse, mutect2, varscan2
- HAS1 | c.129G>C p.G43= | Silent (SNP) | VAF 100/532 reads (19%) | catalogued as rs975588969; called by muse, mutect2, varscan2
- JMJD1C | c.4197C>A p.I1399= | Silent (SNP) | VAF 39/164 reads (24%) | called by muse, mutect2, varscan2
- LUC7L | c.57G>A p.R19= | Silent (SNP) | VAF 41/207 reads (20%) | catalogued as rs972994693; called by muse, mutect2, varscan2
- RHPN1 | c.1915C>A p.R639= | Silent (SNP) | VAF 85/389 reads (22%) | catalogued as rs374961930; called by muse, mutect2, varscan2
- ARIH1 | c.912-26T>G | Intron (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- GYS1 | c.*615T>C | 3'UTR (SNP) | VAF 51/460 reads (11%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6209A>C | Intron (SNP) | VAF 131/578 reads (23%) | called by muse, mutect2, varscan2
- MUC20P1 | n.120C>G | RNA (SNP) | VAF 8/58 reads (14%) | catalogued as rs1449305819; called by mutect2, varscan2
- NXF5 | n.456A>G | RNA (SNP) | VAF 40/146 reads (27%) | called by muse, mutect2, varscan2
- RSAD1 | c.474+91_474+94del | Intron (DEL) | VAF 16/82 reads (20%) | catalogued as rs765772428; called by pindel, varscan2
- SYNE3 | c.*8352T>A | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2
- TRAK1 | c.1744+36C>T | Intron (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- TUBA4A | c.-33G>A | 5'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as rs559586186; called by muse, varscan2
